Somatic mutation profile of tumor specimen TCGA-OR-A5KP-01A (aliquot TCGA-OR-A5KP-01A-11D-A30A-10) from TCGA case TCGA-OR-A5KP, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 45.7 years (16,702 days).
Specimen TCGA-OR-A5KP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a910e7c-a060-41a1-89c2-fc09d3c8c762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KP-10A (Blood Derived Normal), aliquot TCGA-OR-A5KP-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70b3852-9ffb-40ff-81e0-39374018e6e0

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Frame Shift Del 8, Nonsense Mutation 2, In Frame Del 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV53318972; called by muse, mutect2, varscan2
- AMHR2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs1215023004; called by muse, mutect2, varscan2
- AQR | c.2827C>A p.R943S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50042816; called by muse, mutect2
- CCDC81 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs757152208; called by muse, mutect2, varscan2
- CPNE9 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs190521882; called by muse, mutect2, varscan2
- DDX39A | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs188717433; called by muse, mutect2, varscan2
- EPHX1 | c.1108_1110del p.S370del | In Frame Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs745827671; called by pindel, varscan2
- GPNMB | c.1685T>C p.L562P (on ENST00000381990 / NM_001005340.2; = p.L550P on NM_002510.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51699104; called by muse, mutect2, varscan2
- H1-1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs1173063698; called by muse, mutect2, varscan2
- KRT78 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100398580; called by muse, mutect2, varscan2
- MIPEP | c.2080G>C p.V694L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs537985967; called by muse, mutect2, varscan2
- OR10A4 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV65842090; called by mutect2, varscan2
- PCDH7 | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868676399; called by muse, mutect2
- SEZ6L | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); catalogued as rs768547272; called by muse, mutect2, varscan2
- TUBAL3 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV66814455; called by muse, mutect2, varscan2
- UBE3A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV51665572; called by muse, mutect2, varscan2
- VPS35 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV54477965; called by muse, mutect2
- XDH | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.065); catalogued as rs777486975; called by muse, mutect2
- ADAMTS19 | c.1797C>G p.C599W | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP15 | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ATM | c.1886del p.S629Tfs*20 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1647_1650del p.F550Kfs*2 | Frame Shift Del (DEL) | VAF 9/99 reads (9%) | called by mutect2, pindel
- BRDT | c.1722T>A p.C574* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- CABIN1 | c.3713A>G p.H1238R | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC88A | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRIM1 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- DBF4 | c.778del p.S260Vfs*10 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- FBXO42 | c.813del p.K272Sfs*20 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- FZR1 | c.182T>G p.F61C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- HDHD3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- HKDC1 | c.1967A>G p.D656G | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HROB | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- KMT2C | c.14006_14007del p.S4669Cfs*13 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by pindel, varscan2
- MRGPRX4 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NAV3 | c.6118C>A p.Q2040K (on ENST00000397909 / NM_001024383.2; = p.Q2018K on NM_014903.6) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NKAPL | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRK | c.622A>G p.R208G | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR2B | c.2731C>A p.L911I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP1CA | c.671_672del p.S224Ffs*53 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | called by pindel, varscan2
- PRPF38B | c.212_215del p.Y71Sfs*67 | Frame Shift Del (DEL) | VAF 116/336 reads (35%) | called by mutect2, pindel, varscan2
- PRRT3 | c.204_205del p.D68Efs*6 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- RBM39 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, varscan2
- RYR2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SAT1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SCAMP3 | c.537_539del p.L180del | In Frame Del (DEL) | VAF 30/191 reads (16%) | called by mutect2, pindel, varscan2
- SIGLEC5 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- SMC3 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TAF7L | c.267A>C p.E89D | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- TET1 | c.3865A>C p.T1289P | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TNNT2 | c.79T>A p.W27R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); called by mutect2, varscan2
- WWP2 | c.392T>G p.V131G | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZDHHC15 | c.483-1G>C p.X161_splice | Splice Site (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- ZMYM2 | c.3178A>G p.S1060G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADH6 | c.504G>A p.E168= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- C19orf12 | c.153C>T p.F51= (on ENST00000392278 / NM_001031726.3; = p.F40= on NM_031448.6) | Silent (SNP) | VAF 14/76 reads (18%) | called by mutect2, varscan2
- CA14 | c.69G>T p.T23= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs781807174; called by muse, mutect2, varscan2
- CENPI | c.1608G>A p.L536= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1021974244; called by muse, mutect2, varscan2
- DNAH5 | c.8292A>G p.T2764= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- FOXG1 | c.960C>T p.R320= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs1388497817, COSV57399320; called by muse, mutect2
- HEATR6 | c.351G>A p.L117= | Silent (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- HIC2 | c.1143G>A p.G381= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs756566978; called by muse, mutect2, varscan2
- RAI14 | c.1608G>A p.K536= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- SAGE1 | c.2517G>A p.G839= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1556606837; called by muse, mutect2
- STAB1 | c.5307C>T p.A1769= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs145377358; called by muse, mutect2, varscan2
- TIAM2 | c.2754G>T p.R918= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV59702990; called by muse, mutect2, varscan2
- TUBAL3 | c.714G>T p.V238= | Silent (SNP) | VAF 76/321 reads (24%) | catalogued as rs781822090, COSV66814838; called by muse, mutect2, varscan2
- SLC35A3 | c.*614A>G | 3'UTR (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
